Somatic mutation profile of tumor specimen C3L-00143-01 (aliquot CPT0001910012) from CPTAC case C3L-00143, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 69.6 years (25,407 days).
Specimen C3L-00143-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9de241b6-d5ef-435b-8c83-9489c5cce4d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00143-31 (Blood Derived Normal), aliquot CPT0003970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb46b026-e2f0-4276-9e0e-4743dba4453e

The open-access MAF lists 802 somatic variants for this specimen: 526 protein-altering or splice-affecting, 180 silent, 96 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 365, Silent 180, Frame Shift Del 102, Intron 56, Frame Shift Ins 22, 3'UTR 18, Nonsense Mutation 15, Splice Site 12, RNA 7, Splice Region 6, 3'Flank 5, 5'Flank 5.

Variants (750 of 802; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 61/292 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.679-1G>A p.X227_splice | Splice Site (SNP) | VAF 49/204 reads (24%) | catalogued as rs672601324, CS971810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs200018596, CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 182/372 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCB5 | c.1622G>A p.R541Q (on ENST00000404938 / NM_001163941.2; = p.R96Q on NM_178559.6) | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776819013, COSV51718331; called by muse, mutect2, varscan2
- AC092143.1 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs200882568; called by muse, mutect2, varscan2
- ACOT12 | c.1442dup p.S482Vfs*8 | Frame Shift Ins (INS) | VAF 21/105 reads (20%) | catalogued as rs752709684; called by mutect2, pindel, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE3 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769054109; called by muse, mutect2, varscan2
- AGRN | c.3773C>T p.T1258M | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs141842070; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1C8P | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1554792792; called by muse, mutect2, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 90/339 reads (27%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2, varscan2
- ANKRD13C | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52030639; called by muse, mutect2, varscan2
- ANKRD18B | c.1176del p.V393Wfs*11 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs745540260; called by mutect2, pindel, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 55/212 reads (26%) | catalogued as rs770443312, COSV59961800; called by mutect2, pindel, varscan2
- APOA5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770555817; called by muse, mutect2, varscan2
- ARHGAP33 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); catalogued as rs201596534, COSV50130082; called by muse, mutect2, varscan2
- ARVCF | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1164678175, COSV54271279; called by muse, mutect2, varscan2
- ASB13 | c.361del p.L121Cfs*6 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as COSV63090510; called by mutect2, pindel, varscan2
- ASXL1 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1378106478; called by muse, mutect2, varscan2
- ATE1 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56440884; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs1554873914; called by mutect2, pindel
- BABAM2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.264); catalogued as rs1264465715; called by muse, mutect2, varscan2
- BARHL1 | c.946del p.L316Wfs*184 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs752703018; called by mutect2, pindel, varscan2
- BCL3 | c.1224del p.R409Gfs*73 | Frame Shift Del (DEL) | VAF 61/257 reads (24%) | catalogued as COSV51234121; called by mutect2, pindel, varscan2
- BCL9L | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1454475209; called by muse, mutect2, varscan2
- BEST3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as rs117505973; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C1orf105 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1165890145; called by muse, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CACNB2 | c.239G>A p.R80H (on ENST00000324631 / NM_201596.3; = p.R25H on NM_000724.4) | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56650610; called by muse, mutect2, varscan2
- CBX8 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs533102630; called by muse, mutect2, varscan2
- CC2D2A | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as rs749997192, COSV67502420; ClinVar: uncertain significance; called by muse, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC127 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs766544426, COSV99722892; called by muse, mutect2, varscan2
- CCDC154 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1174247599; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC69 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV100815197; called by muse, mutect2, varscan2
- CCP110 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as rs746021450; called by muse, mutect2, varscan2
- CD109 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs775042813; called by muse, mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CGB2 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99041398; called by muse, mutect2, varscan2
- CGN | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373995070; called by muse, mutect2, varscan2
- CHD6 | c.6535C>T p.R2179C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs752745107; called by muse, mutect2, varscan2
- CHI3L2 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462622235; called by muse, mutect2, varscan2
- CHRAC1 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV55270084; called by muse, mutect2, varscan2
- CHRNA2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 145/474 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs757700781; called by muse, mutect2, varscan2
- CLIC1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs764853833, COSV101007526; called by muse, mutect2, varscan2
- CNPY4 | c.41del p.L14Wfs*11 | Frame Shift Del (DEL) | VAF 56/247 reads (23%) | catalogued as rs1347948509; called by mutect2, varscan2
- COL9A3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs368744467; called by muse, mutect2, varscan2
- CPSF1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1554864698, COSV58235698; called by muse, mutect2, varscan2
- CR2 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376371407, COSV100889676; called by muse, mutect2, varscan2
- CRACD | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273455159; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as rs1378599948; called by mutect2, varscan2
- CTAGE9 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 147/686 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs754207048; called by muse, mutect2, varscan2
- CTSA | c.990dup p.C331Lfs*56 | Frame Shift Ins (INS) | VAF 77/371 reads (21%) | catalogued as rs758642867; called by mutect2, varscan2
- CYP11B1 | c.1276del p.Q426Sfs*4 | Frame Shift Del (DEL) | VAF 71/323 reads (22%) | catalogued as rs1249087390; called by mutect2, pindel, varscan2
- CYRIA | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs140297141; called by muse, mutect2, varscan2
- CYTH2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs1336327110; called by muse, mutect2, varscan2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 82/333 reads (25%) | catalogued as rs755674655; called by mutect2, varscan2
- DCLRE1B | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs750020628, COSV56724296; called by muse, mutect2, varscan2
- DENND1C | c.787A>G p.M263V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs1216329037; called by muse, mutect2, varscan2
- DLGAP2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.997); catalogued as COSV101421924; called by muse, mutect2, varscan2
- DMBT1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs755362415; called by muse, mutect2, varscan2
- DMWD | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs555745356, COSV52181350; called by muse, mutect2, varscan2
- DNAH2 | c.7465G>A p.A2489T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as rs538779683, COSV101209100; called by muse, mutect2, varscan2
- DOCK5 | c.4713dup p.T1572Yfs*10 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs745668075; called by mutect2, varscan2
- DPEP3 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs376146876; called by muse, mutect2, varscan2
- EEF2 | c.2332G>A p.G778S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1320271147; called by muse, mutect2, varscan2
- EFNB2 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs374559924; called by muse, mutect2, varscan2
- EMC3 | c.167T>A p.I56N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs1559351897; called by muse, mutect2, varscan2
- EMID1 | c.1251del p.S418Afs*33 | Frame Shift Del (DEL) | VAF 56/204 reads (27%) | catalogued as rs778149597; called by mutect2, pindel, varscan2
- EMILIN3 | c.1380dup p.W461Vfs*31 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | catalogued as rs759858342; called by mutect2, varscan2
- EPB41L4A | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs201974109, COSV54881635; called by muse, mutect2, varscan2
- EPPK1 | c.5147G>A p.R1716H | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as rs781799132; called by muse, mutect2, varscan2
- EPPK1 | c.4619G>A p.S1540N | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782458222; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs753821453; called by mutect2, varscan2
- FANCD2 | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs759348779, COSV55043254; called by muse, mutect2, varscan2
- FDPS | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 64/525 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs961453941; called by muse, varscan2
- FGD6 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as rs1456534134; called by muse, mutect2, varscan2
- FGF3 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376445217; called by muse, mutect2, varscan2
- FHIT | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768734343; called by muse, mutect2, varscan2
- FIGNL1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs139910008; called by muse, mutect2, varscan2
- FLCN | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs767235709, COSV99550202; called by muse, mutect2, varscan2
- FMN1 | c.3748C>T p.P1250S (on ENST00000616417 / NM_001277313.2; = p.P1027S on NM_001103184.4) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV57935190; called by muse, mutect2, varscan2
- FMN2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60446814; called by muse, mutect2
- FOXF1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM135688; called by muse, mutect2, varscan2
- FSIP2 | c.2212T>C p.C738R | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs1289340958; called by muse, mutect2
- GBF1 | c.3739C>T p.L1247F (on ENST00000369983 / NM_001377137.1; = p.L1246F on NM_004193.3) | Missense Mutation (SNP) | VAF 103/437 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761638809; called by muse, mutect2, varscan2
- GLOD4 | c.434G>A p.R145H (on ENST00000301328 / NM_001366247.1; = p.R130H on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56755300; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GPR162 | c.1339C>T p.R447W (on ENST00000311268 / NM_019858.2; = p.R163W on NM_014449.2) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs782490981; called by muse, mutect2, varscan2
- GPR39 | c.575A>C p.N192T | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as COSV61430884; called by muse, mutect2, varscan2
- GPR85 | c.280T>C p.C94R | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51783751; called by muse, mutect2, varscan2
- GRAMD4 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.311); catalogued as rs558233933; called by muse, mutect2, varscan2
- GRM4 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.303); catalogued as rs1414251370, COSV100946840, COSV65211996; called by muse, mutect2, varscan2
- HOOK3 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV56884263; called by muse, mutect2, varscan2
- HS3ST3A1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1300016001; called by muse, mutect2, varscan2
- HSPA2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.958); catalogued as COSV55968508; called by muse, mutect2, varscan2
- IKBKB | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148097786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL17REL | c.213del p.Q72Sfs*12 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs747097955, COSV58008141; called by mutect2, pindel, varscan2
- IRS2 | c.3924del p.P1309Rfs*22 | Frame Shift Del (DEL) | VAF 58/258 reads (22%) | catalogued as rs747968639; called by pindel, varscan2
- ISL1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs769362903, COSV57932054; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 116/507 reads (23%) | catalogued as rs763250381; called by pindel, varscan2
- KAZN | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.562); catalogued as rs1210719282; called by mutect2, varscan2
- KCNC3 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 46/519 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as rs1259120367; called by muse, mutect2
- KCNK17 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs376249168, COSV64686305; called by muse, mutect2, varscan2
- KCNV2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754162112; called by muse, mutect2, varscan2
- KHSRP | c.1919del p.P640Hfs*83 | Frame Shift Del (DEL) | VAF 33/169 reads (20%) | catalogued as COSV101231145; called by mutect2, pindel, varscan2
- KMT2C | c.5957G>A p.R1986Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs138373177; called by muse, mutect2, varscan2
- KMT2D | c.7028C>T p.P2343L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs764884530, COSV99987532; called by muse, mutect2, varscan2
- LAMA2 | c.442del p.R148Gfs*24 | Frame Shift Del (DEL) | VAF 89/328 reads (27%) | catalogued as COSV70345971; called by mutect2, pindel, varscan2
- LCT | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs368148827; called by muse, mutect2, varscan2
- LDHD | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.337); catalogued as rs1041482799, COSV55580777; called by muse, mutect2, varscan2
- LRR1 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV53564018; called by muse, mutect2, varscan2
- LTBP2 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1374074753; called by muse, mutect2, varscan2
- LYN | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs1169208278, COSV72922983; called by muse, mutect2, varscan2
- MAP1A | c.6299A>G p.H2100R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs770795881; called by muse, mutect2, varscan2
- MAP3K9 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs879195926, COSV67120658, COSV67120692; called by muse, mutect2, varscan2
- MARCKSL1 | c.246dup p.K83Qfs*33 | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | catalogued as rs749563695; called by mutect2, varscan2
- MARVELD3 | c.504del p.R169Gfs*40 | Frame Shift Del (DEL) | VAF 47/198 reads (24%) | catalogued as COSV51705736; called by mutect2, pindel, varscan2
- MECOM | c.469G>A p.A157T (on ENST00000468789 / NM_001105078.4; = p.A345T on NM_004991.4) | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99244709; called by muse, mutect2, varscan2
- MED26 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV54660782; called by muse, mutect2, varscan2
- MIA3 | c.503dup p.N168Kfs*3 | Frame Shift Ins (INS) | VAF 20/142 reads (14%) | catalogued as rs756037599; called by mutect2, varscan2
- MICAL2 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780210943; called by muse, mutect2, varscan2
- MOAP1 | c.308del p.L103* | Frame Shift Del (DEL) | VAF 47/196 reads (24%) | catalogued as COSV52094055; called by mutect2, pindel, varscan2
- MPV17 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 132/483 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs112170670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs751646149; called by mutect2, varscan2
- MSL1 | c.142del p.R48Gfs*155 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs1158293640; called by mutect2, pindel, varscan2
- MUC12 | c.13501G>A p.G4501S (on ENST00000379442; = p.G4358S on NM_001164462.1) | Missense Mutation (SNP) | VAF 41/528 reads (8%) | SIFT tolerated (1); catalogued as rs745881653; called by muse, mutect2, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC5B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs774531281, COSV71593181; called by muse, mutect2, varscan2
- MYH15 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs776507202; called by muse, mutect2, varscan2
- MYO15A | c.9965T>C p.L3322P | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52752478; called by muse, mutect2, varscan2
- MYOM1 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs763165458; called by muse, mutect2, varscan2
- MZF1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV53043524; called by muse, mutect2, varscan2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs770577267; called by mutect2, varscan2
- NCAPD3 | c.1531del p.S511Pfs*18 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as COSV101599401; called by mutect2, pindel, varscan2
- NCOA5 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.658); catalogued as rs1481941466; called by muse, mutect2, varscan2
- NEK8 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249612238, COSV52047259; called by muse, mutect2, varscan2
- NEPRO | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202154386; called by muse, mutect2, varscan2
- NFATC1 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); catalogued as rs750241981, COSV53706475; called by muse, mutect2, varscan2
- NINL | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs748754072, COSV53998853, COSV54011508; called by muse, mutect2, varscan2
- NLN | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769012222, COSV66765821; called by muse, mutect2, varscan2
- NOMO1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 134/480 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs1212869644; called by muse, mutect2, varscan2
- NPAP1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs142710386; called by muse, mutect2, varscan2
- NPTN | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1380584815; called by muse, mutect2, varscan2
- NSUN2 | c.1992T>A p.D664E | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV52956918; called by muse, mutect2, varscan2
- NUFIP1 | c.494del p.K165Rfs*38 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs770344882; called by mutect2, varscan2
- NUP210L | c.4409T>C p.M1470T | Missense Mutation (SNP) | VAF 94/472 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs1267882025; called by muse, mutect2, varscan2
- OR2AJ1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1235580981; called by muse, mutect2, varscan2
- OR5A1 | c.317del p.F106Sfs*13 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | catalogued as rs755323345; called by mutect2, varscan2
- OR6P1 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557899887; called by muse, varscan2
- PAPSS2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368617355; called by muse, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 66/293 reads (23%) | catalogued as CM011452; called by mutect2, varscan2
- PCCB | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs1231151514; called by muse, mutect2, varscan2
- PCDHA7 | c.1294T>C p.S432P | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV65347680; called by muse, mutect2, varscan2
- PCDHAC1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53860000; called by muse, mutect2, varscan2
- PCDHGB6 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as COSV53959164; called by muse, mutect2, varscan2
- PELP1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1313600381; called by muse, mutect2, varscan2
- PHETA1 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as COSV100825331; called by muse, mutect2, varscan2
- PI4KA | c.4940C>T p.P1647L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1347180293, COSV55404348; called by muse, mutect2, varscan2
- PLA2G4F | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs775787567, COSV51829753; called by muse, mutect2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | catalogued as rs765091847; called by mutect2, varscan2
- PLXNB3 | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs782668477; called by muse, mutect2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- POLR2A | c.21del p.S8Rfs*19 | Frame Shift Del (DEL) | VAF 57/191 reads (30%) | catalogued as rs762376289; called by mutect2, pindel, varscan2
- PPP1CB | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV56090566; called by muse, mutect2, varscan2
- PPP4R3A | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1463941060, COSV61504257; called by muse, varscan2
- PRDM16 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746868217, COSV54595761; called by muse, mutect2, varscan2
- PRPF19 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776930181, COSV99920530; called by muse, mutect2, varscan2
- PRSS12 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs780765485; called by muse, mutect2, varscan2
- PSMC3 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.553); catalogued as rs777306127; called by muse, varscan2
- PTPN6 | c.1584G>A p.S528= | Splice Region (SNP) | VAF 72/290 reads (25%) | catalogued as rs782111333, COSV59684663; called by muse, varscan2
- RBM44 | c.145C>T p.P49S (on ENST00000611254; = p.P683S on NM_001080504.2) | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765839484; called by muse, mutect2, varscan2
- RBM5 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1345571970; called by muse, mutect2, varscan2
- RC3H1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 35/433 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1307781934; called by muse, mutect2
- RET | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs765654609, COSV60703525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.901); catalogued as rs1563292435, COSV52569840; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.037); catalogued as rs760735885; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAGA | c.197A>G p.Q66R | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998142; called by muse, mutect2, varscan2
- SAMD11 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs766360427; called by muse, mutect2, varscan2
- SAMD4A | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.687); catalogued as rs1056608519; called by muse, mutect2, varscan2
- SCAF4 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as rs867668039, COSV99741855; called by muse, mutect2, varscan2
- SCAMP3 | c.380del p.G127Afs*54 | Frame Shift Del (DEL) | VAF 49/274 reads (18%) | catalogued as COSV56945353; called by mutect2, pindel, varscan2
- SEMA4A | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.17); catalogued as COSV61772994; called by muse, mutect2
- SERGEF | c.322T>G p.C108G | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99787240; called by muse, varscan2
- SF3A2 | c.995del p.P332Qfs*114 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs771822076; called by pindel, varscan2
- SFI1 | c.3199G>A p.A1067T (on ENST00000400288 / NM_001007467.3; = p.A1036T on NM_014775.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs909481339, COSV56717141; called by muse, mutect2, varscan2
- SLC22A2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs758136736; called by muse, mutect2, varscan2
- SLC26A1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs199753982; called by muse, mutect2, varscan2
- SLC34A2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 141/459 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs780162354, COSV65943474; called by muse, mutect2, varscan2
- SLC6A14 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.559); catalogued as rs782606767; called by muse, mutect2, varscan2
- SMARCA4 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758165; called by muse, mutect2, varscan2
- SMTNL2 | c.1348G>A p.V450I (on ENST00000389313 / NM_001114974.2; = p.V306I on NM_198501.3) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144468111; called by muse, mutect2, varscan2
- SNAPC1 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 35/174 reads (20%) | catalogued as rs778933382; called by mutect2, varscan2
- SND1 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756586129; called by muse, mutect2, varscan2
- SOWAHD | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1481038868, COSV59649747; called by muse, mutect2, varscan2
- SOX1 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs918092058, COSV58378469; called by muse, mutect2, varscan2
- SPATA12 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.242); catalogued as rs1398690149; called by muse, mutect2, varscan2
- SPATA31D1 | c.1440G>C p.Q480H | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1367113911; called by muse, mutect2, varscan2
- SPTA1 | c.4193A>G p.Q1398R | Missense Mutation (SNP) | VAF 76/506 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63754370; called by muse, mutect2, varscan2
- ST6GAL2 | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 12/198 reads (6%) | PolyPhen benign (0.009); catalogued as COSV100867810, COSV100868301; called by muse, mutect2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs747003550; called by mutect2, varscan2
- SUZ12 | c.2208dup p.Q737Tfs*20 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs769517721; called by mutect2, pindel
- SYNPO | c.1579C>T p.R527W (on ENST00000394243 / NM_001166208.2; = p.R283W on NM_007286.6) | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs756648276; called by muse, mutect2, varscan2
- SZT2 | c.6948del p.S2317Pfs*17 (on ENST00000634258 / NM_001365999.1; = p.S2260Pfs*17 on NM_015284.4) | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | catalogued as rs753888420; called by mutect2, pindel, varscan2
- TBC1D9B | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1037167441, COSV62281072; called by muse, mutect2, varscan2
- TEAD1 | c.465+1del | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | catalogued as COSV57567740; called by mutect2, varscan2
- TEKT5 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs758598614; called by muse, mutect2, varscan2
- TENM1 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs143931463; called by muse, mutect2, varscan2
- THEMIS | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs763756804, COSV64069599; called by muse, mutect2, varscan2
- TLN1 | c.5684G>A p.R1895H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs567336438, COSV100148179; called by muse, mutect2, varscan2
- TMCO3 | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs568523852; called by muse, mutect2, varscan2
- TMEM132D | c.618dup p.T207Hfs*29 | Frame Shift Ins (INS) | VAF 24/134 reads (18%) | catalogued as rs747811524; called by mutect2, varscan2
- TNFAIP3 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52799106, COSV52799616; called by muse, mutect2, varscan2
- TNFRSF10B | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52390969; called by muse, mutect2, varscan2
- TNN | c.2558C>T p.T853M | Missense Mutation (SNP) | VAF 71/472 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs761263903, COSV53421026; called by muse, mutect2, varscan2
- TOLLIP | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99719446; called by muse, mutect2, varscan2
- TP53BP2 | c.1762G>A p.V588I (on ENST00000343537 / NM_001031685.3; = p.V459I on NM_005426.2) | Missense Mutation (SNP) | VAF 67/427 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as rs138105834; called by muse, mutect2, varscan2
- TRAPPC3L | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs751059408; called by muse, mutect2, varscan2
- TRIM35 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs765088471, COSV59522444; called by muse, mutect2, varscan2
- TRIM54 | c.830C>T p.A277V (on ENST00000380075 / NM_187841.3; = p.A319V on NM_032546.4) | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs970244730; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPC3 | c.683C>T p.T228M (on ENST00000379645 / NM_001366479.2; = p.T155M on NM_003305.2) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199593201, COSV99312638; called by muse, mutect2, varscan2
- TSC2 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs876658578, COSV54758369; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- TSHZ3 | c.3082dup p.M1028Nfs*30 | Frame Shift Ins (INS) | VAF 25/115 reads (22%) | catalogued as rs773668132; called by mutect2, pindel, varscan2
- TTC5 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV51871992; called by muse, mutect2, varscan2
- TXNIP | c.1164_1166del p.N389del | In Frame Del (DEL) | VAF 38/290 reads (13%) | catalogued as rs1553765789; called by pindel, varscan2
- UBR4 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1209286259, COSV64388938; called by muse, mutect2, varscan2
- WSCD1 | c.1466A>G p.H489R | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287983777; called by muse, mutect2, varscan2
- ZFHX4 | c.9130G>A p.D3044N | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50664416; called by muse, mutect2, varscan2
- ZFYVE26 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61331600; called by muse, mutect2, varscan2
- ZNF695 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV60587006; called by muse, mutect2, varscan2
- ZNF7 | c.692del p.K231Sfs*59 | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | catalogued as rs1398210459; called by mutect2, varscan2
- ZNF737 | c.755G>C p.S252T | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782418515, COSV71199373; called by muse, varscan2
- ZNF827 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65224733; called by muse, varscan2
- ZNF862 | c.811dup p.D271Gfs*22 | Frame Shift Ins (INS) | VAF 58/206 reads (28%) | catalogued as rs769847259; called by mutect2, varscan2
- ZXDC | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs993305321, COSV100306591; called by muse, mutect2, varscan2
- AADACL4 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- AADAT | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AAGAB | c.852_856del p.R284Sfs*20 | Frame Shift Del (DEL) | VAF 47/238 reads (20%) | called by mutect2, pindel, varscan2
- AARS2 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB1 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ABCE1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | called by muse, varscan2
- ABL1 | c.1950del p.L651Wfs*43 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 110/398 reads (28%) | called by mutect2, varscan2
- ACACA | c.3049C>T p.R1017* | Nonsense Mutation (SNP) | VAF 62/239 reads (26%) | called by muse, mutect2, varscan2
- ACE | c.702del p.T235Pfs*13 | Frame Shift Del (DEL) | VAF 86/342 reads (25%) | called by mutect2, pindel, varscan2
- ADAM33 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADCY4 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP13 | c.4016T>C p.V1339A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMD1 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANAPC5 | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ANO4 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP1S3 | c.183-1G>T p.X61_splice | Splice Site (SNP) | VAF 66/229 reads (29%) | called by muse, mutect2, varscan2
- APBB3 | c.1461A>C p.*487Yext*9 (on ENST00000357560 / NM_133173.2; = p.*494Yext*9 on NM_006051.3) | Nonstop Mutation (SNP) | VAF 83/318 reads (26%) | called by muse, mutect2, varscan2
- APEX2 | c.1229T>C p.I410T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP44 | c.205T>A p.L69M | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF6 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ARRB2 | c.420C>A p.A140= | Splice Region (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- AS3MT | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ATP13A1 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ATP2A2 | c.2875A>G p.T959A | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2
- ATP6V0D1 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ATP9A | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- ATXN2L | c.2141T>C p.I714T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, varscan2
- BAHCC1 | c.3910C>A p.L1304M | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 69/230 reads (30%) | called by mutect2, pindel, varscan2
- BRD4 | c.3061del p.H1021Ifs*47 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel
- BRPF3 | c.2332C>A p.L778I | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C3orf49 | c.848del p.N283Ifs*2 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel
- C4orf51 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBX6 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC178 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CD163L1 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD6 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CDC42BPA | c.4450C>T p.L1484F (on ENST00000334218 / NM_001366019.2; = p.L1471F on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CEP152 | c.4134del p.K1378Nfs*7 (on ENST00000380950 / NM_001194998.2; = p.K1322Nfs*7 on NM_014985.4) | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- CFAP206 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 33/136 reads (24%) | called by mutect2, pindel, varscan2
- CHRNA1 | c.44-2A>G p.X15_splice | Splice Site (SNP) | VAF 92/351 reads (26%) | called by muse, mutect2, varscan2
- CLASP2 | c.3570dup p.D1191Rfs*2 (on ENST00000359576; = p.D1190Rfs*2 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- CLEC18A | c.217-1G>T p.X73_splice | Splice Site (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- CNTN2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRISP2 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CROCC | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CYP21A2 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DBX1 | c.933del p.S312Rfs*? | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- DEDD | c.419A>T p.Q140L | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DENND4B | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DENND5A | c.2442A>T p.K814N | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHFR2 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DNAH5 | c.3074_3075insA p.A1026Cfs*21 | Frame Shift Ins (INS) | VAF 69/229 reads (30%) | called by mutect2, pindel, varscan2
- DRP2 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.755_756del p.Y252Cfs*67 (on ENST00000361735 / NM_015935.5; = p.Y166Cfs*67 on NM_014955.3) | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- EEF1G | c.659del p.K220Sfs*118 | Frame Shift Del (DEL) | VAF 56/209 reads (27%) | called by mutect2, pindel, varscan2
- EFCAB12 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 79/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EGR2 | c.828del p.S277Vfs*4 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- EIF2AK3 | c.704T>G p.I235S | Missense Mutation (SNP) | VAF 109/383 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- EIF4G1 | c.4201C>T p.L1401F (on ENST00000346169 / NM_198241.3; = p.L1206F on NM_004953.5) | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- EML5 | c.5530T>C p.Y1844H (on ENST00000380664; = p.Y1852H on NM_183387.3) | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- EPC1 | c.1264A>C p.N422H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- EPS8L1 | c.1246T>C p.Y416H (on ENST00000201647 / NM_133180.3; = p.Y289H on NM_017729.3) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERC1 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, varscan2
- EZR | c.12+6T>A | Splice Region (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- FAM83E | c.180T>A p.S60R | Missense Mutation (SNP) | VAF 111/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FLII | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FNDC1 | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNDC1 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSD2 | c.2108del p.F703Sfs*32 | Frame Shift Del (DEL) | VAF 11/119 reads (9%) | called by mutect2, pindel
- GAREM2 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- GATAD1 | c.163_168del p.S55_G56del | In Frame Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- GBA2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GGPS1 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLI2 | c.1364G>A p.C455Y (on ENST00000361492 / NM_001374353.1; = p.C472Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GLIS3 | c.870del p.A291Rfs*110 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- GNL3L | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGB1 | c.4376T>C p.V1459A | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPR179 | c.3869del p.K1290Rfs*12 (on ENST00000621958; = p.K1289Rfs*12 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 42/174 reads (24%) | called by mutect2, pindel, varscan2
- GRIN2D | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GRM2 | c.2264A>C p.N755T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.55); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSDME | c.991-1G>A p.X331_splice | Splice Site (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- GTF2I | c.1169del p.F390Sfs*10 (on ENST00000573035 / NM_032999.4; = p.F349Sfs*10 on NM_001518.5) | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- HCFC1 | c.2696del p.G899Afs*25 | Frame Shift Del (DEL) | VAF 34/184 reads (18%) | called by mutect2, pindel, varscan2
- HCFC2 | c.667T>C p.W223R | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HERC1 | c.13031del p.N4344Mfs*46 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | called by mutect2, varscan2
- HERC2 | c.10462G>A p.A3488T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK3 | c.805A>C p.N269H | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- HLA-DOA | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HORMAD1 | c.848del p.N283Tfs*12 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- HOXC6 | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYAL4 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGSF3 | c.1672T>C p.Y558H (on ENST00000369486 / NM_001007237.3; = p.Y578H on NM_001542.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF9B | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- INAVA | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRX2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISLR | c.704A>C p.Q235P | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ITK | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JMJD7 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6A | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, varscan2
- KIF12 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KIF5C | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLHL28 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.12455T>C p.L4152P | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KNTC1 | c.1661del p.L554Yfs*3 | Frame Shift Del (DEL) | VAF 52/194 reads (27%) | called by mutect2, pindel, varscan2
- LAD1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA1 | c.8397+2T>A p.X2799_splice | Splice Site (SNP) | VAF 95/422 reads (23%) | called by muse, mutect2, varscan2
- LAMA4 | c.4715T>C p.L1572P (on ENST00000230538 / NM_001105206.3; = p.L1565P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA5 | c.7915G>A p.A2639T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 56/187 reads (30%) | called by mutect2, varscan2
- LMX1A | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 93/450 reads (21%) | called by muse, mutect2, varscan2
- LRRC36 | c.2213G>A p.G738D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- LRRC3C | c.119del p.G40Vfs*116 | Frame Shift Del (DEL) | VAF 39/233 reads (17%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.581G>A p.W194* (on ENST00000528054; = p.W163* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 68/313 reads (22%) | called by muse, mutect2, varscan2
- LY6H | c.68-6G>A | Splice Region (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.980C>A p.A327D (on ENST00000510038; = p.A326D on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAGI2 | c.1292del p.K431Rfs*22 | Frame Shift Del (DEL) | VAF 33/154 reads (21%) | called by pindel, varscan2
- MAN1A2 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- MAOA | c.1231T>C p.F411L | Missense Mutation (SNP) | VAF 104/393 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MAP10 | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MAP3K4 | c.2864T>G p.L955R | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP7D1 | c.107del p.P36Hfs*20 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel
- MAPK8IP1 | c.755del p.P252Lfs*24 | Frame Shift Del (DEL) | VAF 43/175 reads (25%) | called by mutect2, pindel, varscan2
- MCEMP1 | c.452G>T p.R151M | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MELTF | c.1978A>G p.M660V | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- METTL6 | c.666del p.F222Lfs*19 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- MFAP5 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MICAL2 | c.5066C>A p.P1689H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MIPOL1 | c.1127T>G p.I376S | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MMS22L | c.2799dup p.V934Sfs*28 | Frame Shift Ins (INS) | VAF 43/191 reads (23%) | called by mutect2, varscan2
- MOB1A | c.411T>C p.G137= | Splice Region (SNP) | VAF 47/223 reads (21%) | called by muse, mutect2, varscan2
- MRPL39 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MTG2 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 134/487 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MUC6 | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBPC1 | c.2222del p.P741Qfs*9 (on ENST00000550270 / NM_206820.2; = p.P766Qfs*9 on NM_002465.4) | Frame Shift Del (DEL) | VAF 96/390 reads (25%) | called by mutect2, varscan2
- MYLPF | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYRF | c.1877G>C p.G626A (on ENST00000278836 / NM_001127392.3; = p.G617A on NM_013279.4) | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- N4BP2 | c.4318A>G p.K1440E | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- N4BP2L1 | c.304del p.R102Efs*6 | Frame Shift Del (DEL) | VAF 60/244 reads (25%) | called by mutect2, varscan2
- NAV1 | c.3425T>A p.L1142* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | called by muse, varscan2
- NCK1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- NCLN | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA2 | c.767T>A p.V256D | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | called by mutect2, varscan2
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 43/176 reads (24%) | called by mutect2, pindel, varscan2
- NEXMIF | c.2372C>A p.T791K | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- NGLY1 | c.367_368del p.K123Vfs*45 | Frame Shift Del (DEL) | VAF 77/286 reads (27%) | called by mutect2, pindel, varscan2
- NKAP | c.407_408dup p.I137Efs*155 | Frame Shift Ins (INS) | VAF 30/156 reads (19%) | called by mutect2, varscan2
- NLE1 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPR2 | c.2008T>G p.S670A | Missense Mutation (SNP) | VAF 77/324 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPR2 | c.2009C>A p.S670* | Nonsense Mutation (SNP) | VAF 76/325 reads (23%) | called by muse, mutect2, varscan2
- NR3C2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, varscan2
- NT5DC3 | c.1391T>C p.M464T | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OAZ1 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OFD1 | c.2795del p.K932Rfs*3 | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | called by mutect2, varscan2
- OLIG2 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- OR2H1 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PACS2 | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PCDHB8 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 94/378 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX2 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PCOLCE | c.176del p.P59Lfs*9 | Frame Shift Del (DEL) | VAF 27/101 reads (27%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.3062G>T p.R1021M | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PDGFRA | c.499del p.V167Wfs*18 | Frame Shift Del (DEL) | VAF 71/302 reads (24%) | called by mutect2, pindel, varscan2
- PDSS2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFN2 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- PITRM1 | c.671G>C p.R224T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PLA2G4F | c.2266del p.R756Afs*47 | Frame Shift Del (DEL) | VAF 60/201 reads (30%) | called by mutect2, pindel, varscan2
- PLG | c.359dup p.N120Kfs*17 | Frame Shift Ins (INS) | VAF 38/210 reads (18%) | called by pindel, varscan2
- POLN | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR1B | c.503del p.G168Afs*4 | Frame Shift Del (DEL) | VAF 46/204 reads (23%) | called by pindel, varscan2
- POR | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PPP1R13B | c.2800C>A p.H934N | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPP1R42 | c.864del p.K288Nfs*2 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1251del p.Y418Tfs*3 | Frame Shift Del (DEL) | VAF 42/157 reads (27%) | called by mutect2, pindel, varscan2
- PRDM2 | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PRKAB2 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PRKCI | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRUNE1 | c.134C>A p.T45K | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PSCA | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- PSEN1 | c.72T>G p.N24K | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRJ | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PVR | c.1010A>G p.H337R | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- RAB3IL1 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RALGAPA2 | c.141dup p.E48* | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- RASGEF1A | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- RASGRP2 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RGS3 | c.2027del p.P676Rfs*159 (on ENST00000350696 / NM_001282923.2; = p.P564Rfs*37 on NM_017790.4) | Frame Shift Del (DEL) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- RGS3 | c.3032C>A p.T1011N (on ENST00000350696 / NM_001282923.2; = p.T730N on NM_130795.4) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS5 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RHBDF1 | c.2245_2247del p.F749del | In Frame Del (DEL) | VAF 56/262 reads (21%) | called by pindel, varscan2
- RLF | c.2339T>C p.I780T | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RMI1 | c.615del p.V206Yfs*5 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | called by mutect2, pindel, varscan2
- RNF165 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RNF213 | c.3584T>C p.V1195A | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- RNF225 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RPS6KL1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- S100A11 | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SAMD7 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAF4 | c.359dup p.N120Kfs*7 | Frame Shift Ins (INS) | VAF 60/220 reads (27%) | called by mutect2, varscan2
- SCYL3 | c.133_134del p.E45Kfs*2 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | called by pindel, varscan2
- SERINC5 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SERPINB7 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETBP1 | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SEZ6L2 | c.1499del p.P500Lfs*73 (on ENST00000308713 / NM_001114099.3; = p.P430Lfs*73 on NM_012410.4) | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | called by mutect2, pindel, varscan2
- SF3A3 | c.1298A>G p.H433R | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SGK2 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- SH2B2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SHPRH | c.2989del p.S997Afs*3 (on ENST00000275233 / NM_001042683.3; = p.S997Vfs*12 on NM_173082.3) | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- SLC17A3 | c.1038-2A>G p.X346_splice | Splice Site (SNP) | VAF 76/307 reads (25%) | called by muse, mutect2, varscan2
- SLC20A1 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC25A4 | c.47del p.G16Afs*44 | Frame Shift Del (DEL) | VAF 59/230 reads (26%) | called by mutect2, pindel, varscan2
- SLC29A3 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SLC4A1AP | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SLC4A7 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SNX2 | c.393T>C p.I131= | Splice Region (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- SOX6 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA32 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRTN | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SRCIN1 | c.2056C>A p.L686I (on ENST00000621492; = p.L652I on NM_025248.3) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SREBF1 | c.3064A>T p.R1022W | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SRRM1 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SS18L1 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- SSC5D | c.4664C>A p.P1555H | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- STK16 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- STX18 | c.479T>A p.V160E | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYDE1 | c.1230del p.G411Afs*21 | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.3903del p.L1302Wfs*8 | Frame Shift Del (DEL) | VAF 48/254 reads (19%) | called by mutect2, pindel, varscan2
- SYTL2 | c.2453+1G>T p.X818_splice (on ENST00000528231 / NM_001162951.2; = p.X794_splice on NM_032943.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- SZT2 | c.4309-2A>G p.X1437_splice (on ENST00000634258 / NM_001365999.1; = p.X1380_splice on NM_015284.4) | Splice Site (SNP) | VAF 50/210 reads (24%) | called by muse, mutect2, varscan2
- TAOK3 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TAS2R60 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBL1X | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TCP1 | c.308del p.N103Mfs*5 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | called by mutect2, pindel, varscan2
- TECTA | c.3805A>G p.S1269G | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- TEX36 | c.23A>C p.N8T | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TFB2M | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 91/519 reads (18%) | called by muse, mutect2, varscan2
- TMEM121B | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM19 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- TMEM68 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFSF4 | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNKS2 | c.3271A>G p.I1091V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNR | c.637dup p.V213Gfs*10 | Frame Shift Ins (INS) | VAF 59/329 reads (18%) | called by mutect2, pindel, varscan2
- TOM1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPR | c.7036+1G>A p.X2346_splice | Splice Site (SNP) | VAF 36/198 reads (18%) | called by muse, varscan2
- TRIB1 | c.189del p.G64Afs*36 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- TRMT6 | c.668-2A>G p.X223_splice | Splice Site (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2
- TRPV6 | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTC38 | c.1106A>G p.H369R | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTLL4 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TUBB2B | c.1303dup p.E435Gfs*89 | Frame Shift Ins (INS) | VAF 32/180 reads (18%) | called by mutect2, pindel
- TXNDC16 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TXNDC17 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- UBR4 | c.9890A>C p.D3297A | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UHMK1 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, varscan2
- ULK1 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- UNKL | c.50del p.P17Rfs*12 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- USP4 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- VLDLR | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSIG10L | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.762); called by muse, varscan2
- WASHC5 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDR45B | c.979dup p.E327Gfs*16 | Frame Shift Ins (INS) | VAF 109/478 reads (23%) | called by mutect2, pindel, varscan2
- WDR59 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- YES1 | c.158A>T p.N53I | Missense Mutation (SNP) | VAF 97/385 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- YLPM1 | c.2170T>G p.S724A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel
- ZBTB37 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZBTB47 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H12B | c.2071del p.Q691Sfs*7 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- ZGPAT | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
- ZGRF1 | c.6064dup p.R2022Kfs*8 | Frame Shift Ins (INS) | VAF 42/217 reads (19%) | called by mutect2, pindel, varscan2
- ZKSCAN3 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 84/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZMYM3 | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZNF135 | c.1411T>C p.C471R (on ENST00000313434 / NM_001289401.2; = p.C483R on NM_003436.4) | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF256 | c.452del p.G151Afs*6 | Frame Shift Del (DEL) | VAF 108/405 reads (27%) | called by mutect2, pindel, varscan2
- ZNF277 | c.1127T>C p.M376T | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF347 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- ZNF521 | c.3404del p.G1135Dfs*2 | Frame Shift Del (DEL) | VAF 43/202 reads (21%) | called by mutect2, pindel, varscan2
- ZNF808 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ZXDB | c.1888T>C p.S630P | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCB10 | c.747T>G p.T249= | Silent (SNP) | VAF 67/367 reads (18%) | called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.741C>T p.G247= | Silent (SNP) | VAF 102/404 reads (25%) | called by muse, mutect2, varscan2
- ACBD4 | c.723C>T p.C241= (on ENST00000376955 / NM_001378111.1; = p.Q245* on NM_024722.4) | Silent (SNP) | VAF 68/311 reads (22%) | called by muse, mutect2, varscan2
- ACTB | c.486T>A p.T162= | Silent (SNP) | VAF 54/213 reads (25%) | called by muse, mutect2, varscan2
- ACTN2 | c.1635C>G p.V545= | Silent (SNP) | VAF 81/442 reads (18%) | called by muse, mutect2, varscan2
- ADAM32 | c.996C>T p.D332= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as rs368424322; called by muse, mutect2, varscan2
- ADCYAP1 | c.168G>A p.S56= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as rs1160337598; called by mutect2, varscan2
- ADNP | c.1944A>G p.Q648= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs201258191; called by muse, mutect2, varscan2
- ADRA2A | c.582C>T p.G194= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs774481735; called by muse, mutect2, varscan2
- AMPD2 | c.2085A>G p.L695= | Silent (SNP) | VAF 132/486 reads (27%) | called by muse, mutect2, varscan2
- ANGPT4 | c.645C>T p.S215= | Silent (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7377G>A p.T2459= | Silent (SNP) | VAF 84/305 reads (28%) | catalogued as rs1262286187; called by muse, mutect2, varscan2
- ARAP1 | c.3714G>A p.A1238= (on ENST00000393609 / NM_001040118.2; = p.A993= on NM_015242.4) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs374999551; called by muse, mutect2, varscan2
- ARHGEF5 | c.999A>C p.P333= | Silent (SNP) | VAF 119/739 reads (16%) | called by muse, mutect2, varscan2
- ASB4 | c.747T>C p.D249= | Silent (SNP) | VAF 71/280 reads (25%) | catalogued as rs1286348787; called by muse, mutect2, varscan2
- ATG2B | c.633T>C p.H211= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- ATP2A2 | c.2853C>A p.P951= | Silent (SNP) | VAF 83/363 reads (23%) | called by muse, mutect2, varscan2
- ATRX | c.6465A>G p.G2155= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as rs782798399; called by muse, mutect2, varscan2
- AVPR1B | c.1134G>A p.T378= | Silent (SNP) | VAF 46/278 reads (17%) | catalogued as rs782145142; called by muse, mutect2, varscan2
- BCAR1 | c.1614T>C p.H538= | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- BCAS3 | c.2529C>T p.F843= (on ENST00000390652 / NM_001353144.2; = p.F828= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs1309211320; called by muse, mutect2, varscan2
- BOK | c.211C>T p.L71= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs752782219; called by muse, varscan2
- BRWD1 | c.654C>T p.G218= | Silent (SNP) | VAF 53/205 reads (26%) | catalogued as rs772205035; called by muse, varscan2
- BTNL8 | c.189G>A p.V63= | Silent (SNP) | VAF 80/379 reads (21%) | called by muse, mutect2, varscan2
- C12orf42 | c.687C>T p.P229= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as rs1403964707; called by muse, mutect2, varscan2
- CALB1 | c.268C>T p.L90= | Silent (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- CAPNS1 | c.138C>A p.G46= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV55822587; called by muse, varscan2
- CASKIN2 | c.1665G>A p.L555= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs201290497, COSV100050422; called by muse, mutect2, varscan2
- CCDC6 | c.672T>C p.L224= | Silent (SNP) | VAF 52/133 reads (39%) | called by muse, varscan2
- CCDC92 | c.648G>A p.P216= | Silent (SNP) | VAF 64/294 reads (22%) | catalogued as rs367866326; called by muse, varscan2
- CDH22 | c.2421G>T p.P807= | Silent (SNP) | VAF 76/276 reads (28%) | called by muse, mutect2, varscan2
- CEP131 | c.1560T>C p.D520= (on ENST00000269392 / NM_001319228.2; = p.D517= on NM_014984.4) | Silent (SNP) | VAF 37/138 reads (27%) | called by muse, mutect2, varscan2
- CERCAM | c.1359T>C p.P453= | Silent (SNP) | VAF 53/252 reads (21%) | called by muse, mutect2, varscan2
- CFAP65 | c.3675T>C p.T1225= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- CHST1 | c.828C>T p.C276= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV57321601; called by muse, mutect2, varscan2
- CLCN6 | c.357G>A p.E119= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs374436040; called by muse, mutect2, varscan2
- CLRN2 | c.528C>T p.F176= | Silent (SNP) | VAF 88/408 reads (22%) | catalogued as COSV71825204; called by muse, mutect2, varscan2
- CMTM1 | c.264A>T p.T88= (on ENST00000457188 / NM_181269.3; = p.T205= on NM_052999.4) | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs1427101165; called by muse, varscan2
- COL2A1 | c.4329T>C p.G1443= | Silent (SNP) | VAF 109/449 reads (24%) | called by muse, mutect2, varscan2
- COL4A4 | c.1170A>G p.P390= | Silent (SNP) | VAF 45/206 reads (22%) | called by muse, mutect2, varscan2
- COL4A6 | c.3678G>A p.G1226= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- CPNE2 | c.522G>A p.K174= | Silent (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- CTSE | c.612A>G p.P204= (on ENST00000360218; = p.P199= on NM_001910.4) | Silent (SNP) | VAF 80/461 reads (17%) | catalogued as COSV100733498; called by muse, mutect2, varscan2
- CYP2D6 | c.1110C>A p.V370= | Silent (SNP) | VAF 128/648 reads (20%) | catalogued as COSV62243482; called by muse, mutect2, varscan2
- DAGLA | c.702C>T p.S234= | Silent (SNP) | VAF 63/230 reads (27%) | catalogued as rs146061723; called by muse, mutect2, varscan2
- DAO | c.603G>A p.Q201= | Silent (SNP) | VAF 55/216 reads (25%) | catalogued as COSV99948445; called by muse, mutect2, varscan2
- DDX11 | c.1914G>C p.G638= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as rs763819207; called by muse, mutect2, varscan2
- DENND4A | c.3774G>A p.K1258= | Silent (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- DGCR6L | c.324G>A p.R108= | Silent (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- DHX8 | c.580C>A p.R194= | Silent (SNP) | VAF 73/224 reads (33%) | called by muse, mutect2, varscan2
- DNAH3 | c.6570G>A p.G2190= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV54510490; called by muse, mutect2, varscan2
- DNAH5 | c.2049G>T p.R683= | Silent (SNP) | VAF 47/207 reads (23%) | called by muse, mutect2, varscan2
- EIF4G1 | c.4653C>T p.D1551= (on ENST00000346169 / NM_198241.3; = p.D1356= on NM_004953.5) | Silent (SNP) | VAF 130/452 reads (29%) | catalogued as rs376080760; called by muse, mutect2, varscan2
- EMD | c.66G>A p.P22= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as rs1557182206, COSV63962505; called by muse, mutect2, varscan2
- FARP1 | c.1401G>A p.P467= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1373064498, COSV60334139; called by muse, varscan2
- FCHO1 | c.2325G>A p.R775= | Silent (SNP) | VAF 123/442 reads (28%) | catalogued as COSV53184277; called by muse, mutect2, varscan2
- FRRS1L | c.642A>G p.R214= | Silent (SNP) | VAF 69/306 reads (23%) | called by muse, mutect2, varscan2
- GC | c.165C>T p.G55= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- GIPC1 | c.355C>T p.L119= | Silent (SNP) | VAF 39/163 reads (24%) | called by muse, mutect2, varscan2
- HMGCS2 | c.840G>A p.Q280= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- IFITM2 | c.91C>T p.L31= | Silent (SNP) | VAF 63/321 reads (20%) | catalogued as rs1376561777, COSV67714999; called by muse, mutect2, varscan2
- IGFBP6 | c.651G>A p.R217= | Silent (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- IRF2BPL | c.288G>C p.A96= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs772041179; called by muse, varscan2
- IRX3 | c.18G>T p.L6= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
- JUP | c.366G>A p.L122= | Silent (SNP) | VAF 86/357 reads (24%) | called by muse, mutect2, varscan2
- KCNC4 | c.1053C>T p.F351= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as rs757033659, COSV63926357; called by muse, mutect2, varscan2
- KCNH3 | c.1584C>T p.H528= | Silent (SNP) | VAF 76/335 reads (23%) | catalogued as COSV99234880; called by muse, mutect2, varscan2
- KCNH5 | c.2616C>T p.D872= | Silent (SNP) | VAF 73/242 reads (30%) | catalogued as rs114036533; called by muse, mutect2, varscan2
- KIAA0895 | c.402T>C p.C134= (on ENST00000297063 / NM_001100425.2; = p.C83= on NM_015314.3) | Silent (SNP) | VAF 48/134 reads (36%) | called by muse, varscan2
- KIAA1586 | c.858C>T p.Y286= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1407985862; called by muse, mutect2, varscan2
- KLK15 | c.78C>T p.D26= | Silent (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- KNDC1 | c.1996C>T p.L666= | Silent (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- LGALS9C | c.615A>G p.G205= | Silent (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- LILRA6 | c.1317C>T p.H439= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as rs755182340, COSV54427582; called by muse, mutect2, varscan2
- LRRC7 | c.2484C>T p.N828= (on ENST00000651989 / NM_001370785.2; = p.N795= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- MARCHF6 | c.460C>T p.L154= | Silent (SNP) | VAF 72/288 reads (25%) | catalogued as rs1052332002; called by muse, mutect2, varscan2
- MCM7 | c.1219C>A p.R407= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- MCUB | c.717G>A p.T239= | Silent (SNP) | VAF 46/203 reads (23%) | catalogued as rs774598514, COSV99488583; called by muse, mutect2, varscan2
- MDN1 | c.6240A>G p.A2080= | Silent (SNP) | VAF 79/319 reads (25%) | catalogued as rs1238643958; called by muse, mutect2, varscan2
- MEGF8 | c.723G>A p.L241= | Silent (SNP) | VAF 52/264 reads (20%) | called by muse, mutect2, varscan2
- MEOX1 | c.99A>G p.S33= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- MID2 | c.402C>T p.S134= | Silent (SNP) | VAF 60/217 reads (28%) | catalogued as rs761567068, COSV99465885; called by muse, mutect2, varscan2
- MISP | c.1545C>T p.D515= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as rs368614247; called by muse, mutect2, varscan2
- MPRIP | c.2037C>T p.L679= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs777391990; called by muse, varscan2
- MTARC1 | c.495C>T p.T165= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as rs200766630; called by muse, mutect2
- MTCL1 | c.4941C>T p.G1647= (on ENST00000306329 / NM_001378206.1; = p.G1328= on NM_015210.4) | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- MTUS2 | c.669C>T p.H223= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs781473869, COSV101462337; called by muse, mutect2, varscan2
- MYBBP1A | c.3663A>G p.P1221= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs769058681; called by muse, mutect2, varscan2
- MYO15B | c.7857C>T p.P2619= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs558817550, COSV101640089; called by muse, mutect2, varscan2
- MYOM1 | c.1533T>C p.A511= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1157854511; called by muse, mutect2, varscan2
- MYOM2 | c.1194C>T p.Y398= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as rs376175215; called by muse, mutect2, varscan2
- NAF1 | c.621T>C p.I207= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- NAPSA | c.501C>T p.F167= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs766421553, COSV99515965; called by muse, mutect2, varscan2
- NCAPG2 | c.732C>T p.H244= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs372309426; called by muse, mutect2, varscan2
- NDRG1 | c.477C>T p.G159= | Silent (SNP) | VAF 85/360 reads (24%) | catalogued as rs747948344; called by muse, mutect2, varscan2
- NEIL3 | c.162T>G p.A54= | Silent (SNP) | VAF 41/152 reads (27%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4398G>A p.Q1466= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- NPBWR2 | c.588C>T p.S196= | Silent (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- NRXN2 | c.519G>A p.P173= | Silent (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- NUDC | c.552G>A p.A184= | Silent (SNP) | VAF 58/283 reads (20%) | catalogued as rs1398481844; called by muse, mutect2, varscan2
- NUMA1 | c.693T>C p.D231= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- NUP37 | c.958T>C p.L320= | Silent (SNP) | VAF 41/131 reads (31%) | called by muse, mutect2, varscan2
- OBSCN | c.765G>A p.A255= | Silent (SNP) | VAF 77/368 reads (21%) | called by muse, mutect2, varscan2
- OR2A4 | c.720C>T p.C240= | Silent (SNP) | VAF 121/415 reads (29%) | catalogued as rs771926925; called by muse, mutect2, varscan2
- OR52K2 | c.813C>A p.A271= | Silent (SNP) | VAF 51/247 reads (21%) | called by muse, mutect2, varscan2
- OR8D2 | c.171T>C p.P57= | Silent (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- OTUD7B | c.969G>T p.G323= | Silent (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- PAK4 | c.639G>A p.T213= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs570041919; called by muse, mutect2, varscan2
- PC | c.276C>T p.P92= | Silent (SNP) | VAF 10/252 reads (4%) | catalogued as rs1475855830; called by muse, mutect2
- PCDHA7 | c.1746G>A p.P582= | Silent (SNP) | VAF 131/488 reads (27%) | catalogued as rs1554135628, COSV65342351; called by muse, mutect2, varscan2
- PCDHGA12 | c.654C>T p.G218= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV52763088; called by muse, mutect2, varscan2
- PCDHGC4 | c.1062A>G p.S354= | Silent (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- PDE4DIP | c.2676C>A p.A892= | Silent (SNP) | VAF 76/435 reads (17%) | catalogued as rs1421906007; called by muse, mutect2, varscan2
- PEX6 | c.2229T>C p.H743= | Silent (SNP) | VAF 79/296 reads (27%) | catalogued as rs145849057; ClinVar: likely benign; called by muse, mutect2, varscan2
- PI4KB | c.1362C>T p.N454= (on ENST00000368873 / NM_001369623.1; = p.N466= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 56/328 reads (17%) | catalogued as rs1214114622, COSV55017859; called by muse, mutect2, varscan2
- PKHD1L1 | c.1393C>T p.L465= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- PLD2 | c.831G>A p.R277= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as rs1264896939; called by muse, mutect2, varscan2
- PLEKHS1 | c.72A>G p.S24= (on ENST00000369310 / NM_182601.1; = p.S30= on NM_024889.5) | Silent (SNP) | VAF 55/216 reads (25%) | called by muse, varscan2
- POFUT2 | c.498G>A p.L166= | Silent (SNP) | VAF 56/195 reads (29%) | catalogued as rs1197507871; called by muse, mutect2, varscan2
- POGK | c.591C>T p.R197= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- POGZ | c.3600T>C p.S1200= | Silent (SNP) | VAF 34/216 reads (16%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.2031G>A p.T677= (on ENST00000318304 / NM_177444.3; = p.T671= on NM_003622.4) | Silent (SNP) | VAF 66/242 reads (27%) | called by muse, mutect2, varscan2
- PPIAL4D | c.447T>C p.N149= | Silent (SNP) | VAF 106/974 reads (11%) | catalogued as rs1362097829; called by muse, mutect2, varscan2
- PRDM10 | c.543G>A p.A181= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs773798562, COSV58805423; called by muse, mutect2, varscan2
- PRPF8 | c.4281G>A p.R1427= | Silent (SNP) | VAF 130/502 reads (26%) | catalogued as rs1416481894; called by muse, mutect2, varscan2
- PRRC2B | c.1473G>A p.R491= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- PSMD8 | c.543G>A p.Q181= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV99287835; called by muse, mutect2, varscan2
- PTPRQ | c.4383A>T p.T1461= (on ENST00000616559; = p.T1419= on NM_001145026.2) | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2
- RAPGEF2 | c.3039C>T p.D1013= | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- RASGRP3 | c.882C>T p.C294= | Silent (SNP) | VAF 79/276 reads (29%) | catalogued as rs375688195; called by muse, mutect2, varscan2
- RBM4 | c.339T>C p.Y113= | Silent (SNP) | VAF 61/222 reads (27%) | called by muse, mutect2, varscan2
- RBM45 | c.645T>C p.H215= | Silent (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- RETREG1 | c.732C>T p.S244= (on ENST00000306320 / NM_001034850.2; = p.S103= on NM_019000.4) | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as rs375825002; called by muse, mutect2, varscan2
- RGS6 | c.1080A>G p.S360= | Silent (SNP) | VAF 50/280 reads (18%) | called by muse, mutect2, varscan2
- RNASEH2C | c.414T>A p.P138= | Silent (SNP) | VAF 121/440 reads (28%) | called by muse, mutect2, varscan2
- ROGDI | c.153C>T p.G51= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs1220300713; called by muse, mutect2, varscan2
- RPH3AL | c.891T>C p.P297= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs1567555115; called by muse, mutect2, varscan2
- RSPO4 | c.258C>T p.N86= | Silent (SNP) | VAF 70/314 reads (22%) | catalogued as rs752655381; called by muse, mutect2, varscan2
- SALL3 | c.3114C>T p.D1038= | Silent (SNP) | VAF 95/363 reads (26%) | catalogued as rs765530573; called by muse, mutect2, varscan2
- SCARA3 | c.330G>A p.P110= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs553147900; called by muse, varscan2
- SCN1A | c.1524G>A p.E508= | Silent (SNP) | VAF 89/352 reads (25%) | catalogued as COSV57667177; called by muse, varscan2
- SCNN1B | c.63G>A p.T21= | Silent (SNP) | VAF 49/178 reads (28%) | catalogued as rs768575842, COSV56302415; called by muse, mutect2, varscan2
- SCUBE3 | c.2013T>C p.L671= | Silent (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- SHANK3 | c.2397G>A p.P799= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs959821547; called by muse, mutect2, varscan2
- SHROOM3 | c.2589C>T p.C863= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs1221156821; called by muse, mutect2, varscan2
- SIK3 | c.1686A>G p.P562= (on ENST00000445177 / NM_001366686.2; = p.P568= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- SLC16A12 | c.162C>T p.G54= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs914304986; called by muse, mutect2, varscan2
- SLC22A2 | c.1188C>T p.L396= | Silent (SNP) | VAF 82/319 reads (26%) | catalogued as rs148232573; called by muse, mutect2, varscan2
- SLC27A1 | c.180G>T p.V60= | Silent (SNP) | VAF 29/137 reads (21%) | called by muse, varscan2
- SLC2A7 | c.357C>A p.A119= | Silent (SNP) | VAF 43/203 reads (21%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2424T>A p.P808= | Silent (SNP) | VAF 38/132 reads (29%) | called by muse, varscan2
- SMURF2 | c.2067G>A p.L689= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV52313955; called by muse, mutect2, varscan2
- SOWAHA | c.24C>T p.A8= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- SOX2 | c.96C>T p.G32= | Silent (SNP) | VAF 73/284 reads (26%) | catalogued as COSV57620858; called by muse, mutect2, varscan2
- SPINT2 | c.171T>C p.N57= | Silent (SNP) | VAF 62/286 reads (22%) | catalogued as rs755846896; called by muse, mutect2, varscan2
- STARD9 | c.8625G>A p.Q2875= | Silent (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- STX11 | c.399C>T p.N133= | Silent (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- STYX | c.249A>G p.L83= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- TACO1 | c.492T>C p.I164= | Silent (SNP) | VAF 95/370 reads (26%) | catalogued as rs779605896; called by muse, mutect2, varscan2
- TLE3 | c.1638G>A p.T546= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs371741462; called by muse, mutect2, varscan2
- TLX3 | c.255A>G p.A85= | Silent (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- TMED8 | c.934C>T p.L312= | Silent (SNP) | VAF 10/225 reads (4%) | catalogued as COSV53625301; called by muse, mutect2
- TMEM63B | c.16C>T p.L6= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV52481458; called by muse, mutect2, varscan2
- TMUB2 | c.309A>G p.S103= (on ENST00000538716 / NM_001353177.2; = p.S83= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TNPO2 | c.2613T>C p.V871= (on ENST00000425528 / NM_001382240.1; = p.V861= on NM_013433.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- TREX2 | c.42G>A p.P14= | Silent (SNP) | VAF 72/275 reads (26%) | catalogued as rs782555276; called by muse, mutect2, varscan2
- TRIB1 | c.550C>A p.R184= | Silent (SNP) | VAF 59/297 reads (20%) | called by muse, mutect2, varscan2
- TRIM67 | c.231C>T p.C77= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- TRIM71 | c.834C>T p.C278= | Silent (SNP) | VAF 78/345 reads (23%) | called by muse, mutect2, varscan2
- TRPC4AP | c.91C>A p.R31= | Silent (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- TUSC3 | c.649T>C p.L217= | Silent (SNP) | VAF 62/253 reads (25%) | called by muse, varscan2
- USP18 | c.294C>T p.S98= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs749385787; called by muse, varscan2
- VARS1 | c.3042G>A p.Q1014= | Silent (SNP) | VAF 51/216 reads (24%) | called by muse, mutect2, varscan2
- VPS13B | c.9858C>T p.S3286= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as rs147242148; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR7 | c.1824C>T p.N608= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as rs373921210; called by muse, mutect2, varscan2
- XKR4 | c.1620C>T p.D540= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs771129861, COSV59302675; called by muse, mutect2, varscan2
- ZFP82 | c.15A>G p.S5= | Silent (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.1098G>A p.L366= | Silent (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- ZNF318 | c.1083G>A p.S361= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as rs747286511; called by muse, mutect2, varscan2
- ZNF562 | c.909T>C p.F303= (on ENST00000453372 / NM_001130032.2; = p.F231= on NM_017656.4) | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*827T>C | 3'UTR (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516513 C>T | 3'Flank (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- AL669831.6 | chr1:786373 ins TTAT | 3'Flank (INS) | VAF 36/186 reads (19%) | called by mutect2, varscan2
- ALOXE3 | c.-313-68G>A | Intron (SNP) | VAF 36/189 reads (19%) | catalogued as COSV100502892; called by muse, mutect2, varscan2
- AP2A2 | c.2297-36T>C | Intron (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- ARHGAP36 | c.-193G>T | 5'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-3214T>G | Intron (SNP) | VAF 28/96 reads (29%) | catalogued as rs1383006749; called by muse, mutect2, varscan2
- ATOH8 | c.960+8562A>C | Intron (SNP) | VAF 61/259 reads (24%) | called by muse, mutect2, varscan2
- ATRX | c.4557+22C>T | Intron (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- BBS2 | c.1397+41T>C | Intron (SNP) | VAF 32/130 reads (25%) | called by muse, mutect2, varscan2
- BIRC7 | c.450-160C>T | Intron (SNP) | VAF 25/114 reads (22%) | catalogued as rs1440160240; called by muse, mutect2, varscan2
- BTNL10 | n.589C>T | RNA (SNP) | VAF 69/511 reads (14%) | called by muse, mutect2, varscan2
- C17orf58 | c.103+99del | Intron (DEL) | VAF 34/131 reads (26%) | called by mutect2, pindel, varscan2
- C22orf15 | c.251-46C>A | Intron (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- CEP43 | c.103-4del | Intron (DEL) | VAF 29/97 reads (30%) | catalogued as rs768165003; called by mutect2, varscan2
- CFAP74 | c.2176+397G>A | Intron (SNP) | VAF 95/365 reads (26%) | called by muse, mutect2, varscan2
- CNIH2 | c.456-33C>T | Intron (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- CTAGE1 | c.*905del | 3'UTR (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel
- CXCL6 | c.*18G>A | 3'UTR (SNP) | VAF 17/67 reads (25%) | catalogued as rs1355366186; called by muse, mutect2, varscan2
- DDB1 | c.665-108T>A | Intron (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- DNAH5 | c.7408-18del | Intron (DEL) | VAF 28/144 reads (19%) | catalogued as rs763542767; called by mutect2, varscan2
- ECM1 | c.224-23C>T | Intron (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- EIPR1 | c.259+19088C>A | Intron (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- ELK1 | chrX:47650539 T>C | 5'Flank (SNP) | VAF 18/67 reads (27%) | catalogued as rs761039114; called by muse, mutect2, varscan2
- ENTPD3 | c.168+2262G>A | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as rs749432976; called by muse, mutect2, varscan2
- ERBIN | c.3634-3264A>G | Intron (SNP) | VAF 38/125 reads (30%) | catalogued as rs762680029; called by muse, mutect2, varscan2
- FAM182A | n.985C>T | RNA (SNP) | VAF 88/641 reads (14%) | catalogued as rs1305456640; called by muse, varscan2
- FOXP2 | c.1094+21del | Intron (DEL) | VAF 46/154 reads (30%) | catalogued as rs749234223; called by mutect2, varscan2
- HAND2-AS1 | n.512+1185del | Intron (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2373+47A>G | Intron (SNP) | VAF 34/130 reads (26%) | catalogued as rs933567615; called by muse, mutect2
- HERC2P3 | n.1264C>A | RNA (SNP) | VAF 65/469 reads (14%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29727025 ins T | 3'Flank (INS) | VAF 36/214 reads (17%) | catalogued as rs17875385; called by mutect2, varscan2
- IFNGR1 | c.*50T>A | 3'UTR (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- IFT80 | c.1315+1645del | Intron (DEL) | VAF 9/23 reads (39%) | catalogued as rs752029701; called by mutect2, varscan2
- IGSF1 | c.-216G>T | 5'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- IL5RA | c.994+2064dup | Intron (INS) | VAF 30/115 reads (26%) | catalogued as rs1277784477; called by mutect2, pindel, varscan2
- ITGB2 | c.-3-9C>A | Intron (SNP) | VAF 51/197 reads (26%) | catalogued as rs376748153; called by muse, mutect2, varscan2
- KIF28P | n.2478G>A | RNA (SNP) | VAF 33/221 reads (15%) | catalogued as rs180803559; called by muse, mutect2, varscan2
- KLC1 | c.*1937_*1962del | 3'UTR (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- LAT | chr16:28984906 del G | 5'Flank (DEL) | VAF 18/75 reads (24%) | catalogued as rs749637413; called by mutect2, varscan2
- LGALS3 | c.597+755C>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- LHX2 | chr9:124007995 del G | 5'Flank (DEL) | VAF 59/249 reads (24%) | called by mutect2, pindel, varscan2
- LILRB5 | c.1255+114del | Intron (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- LINC01148 | n.339T>C | RNA (SNP) | VAF 7/46 reads (15%) | catalogued as rs554662736; called by muse, mutect2, varscan2
52 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 52 other) are not listed here.
